Gene-level copy-number profile of tumor specimen TCGA-3H-AB3X-01A from TCGA case TCGA-3H-AB3X, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 62.2 years (22,702 days).
Specimen TCGA-3H-AB3X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.41b7c449-47f2-470f-9f92-f3a4a02c8549.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3H-AB3X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d6d101a-fe41-42f9-9dcd-1087d6aaac1d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 11,490; copy number 2: 41,991; copy number 3: 3,715; copy number 4: 2,604; copy number 5: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3H-AB3X-01A-11D-A39Q-01): tumor purity 0.74, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,387,729–184,625,030, 8 genes: IRF2, SNORD79, AC099343.2, IRF2-DT, AC099343.3, LINC02427, AC099343.1, LINC02365.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,330,935, 12 genes, copy number 5 (within-gene range 2–5): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.

Autosomal genes at a single copy (total copy number 1): 10,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
